Gene-level copy-number profile of tumor specimen TCGA-58-A46K-01A from TCGA case TCGA-58-A46K, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.9 years (21,867 days).
Specimen TCGA-58-A46K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4e084153-62f6-429e-ad6a-8ef7819ae32d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-A46K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3f620ec9-bc98-42f3-8e8f-7288855bc8e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 14; copy number 2: 25,943; copy number 3: 16,546; copy number 4: 14,359; copy number 5: 1,316; copy number 6: 687; copy number 7: 223; copy number 8: 150; copy number 9: 290; copy number 10: 263; copy number 12: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-A46K-01A-11D-A24C-01): tumor purity 0.61, ploidy 1.54, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,370,123–90,370,427, 1 gene: RN7SKP248.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,949 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–150,913,292, 281 genes, copy number 5 (broad region; genes not listed).
- chr1:236,348,257–244,451,909, 128 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:93,843,764–117,139,389, 322 genes, copy number 5 (broad region; genes not listed).
- chr3:131,325,092–192,917,856, 978 genes, copy number 5–12 (broad region; genes not listed).
- chr3:195,544,048–198,222,513, 112 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5–8 (broad region; genes not listed).
- chr8:125,859,721–128,564,679, 43 genes, copy number 5 (within-gene range 4–5): LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr11:127,188,885–128,587,558, 11 genes, copy number 5: AP003121.1, LINC02712, RN7SKP121, RN7SKP279, AP003532.1, DNAJB6P1, LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1.
- chr11:132,414,977–133,532,519, 1 gene, copy number 5 (within-gene range 2–5): OPCML.
- chr11:132,771,623–135,075,908, 38 genes, copy number 5: AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:65,589,111–69,579,793, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:129,013,336–129,904,025, 12 genes, copy number 6: NLRP9P1, TMEM132D, TMEM132D-AS1, AC107033.1, TMEM132D-AS2, AC079456.1, AC130404.1, AC130404.2, AC117373.1, AC117373.2, AC055717.3, AC055717.1.
- chr17:26,981,694–29,404,105, 141 genes, copy number 6 (broad region; genes not listed).
- chr17:29,390,662–29,424,867, 2 genes, copy number 6: MIR4523, RNU6-711P.
- chr17:31,391,675–34,174,964, 82 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
